Somatic mutation profile of tumor specimen ALCH-ADUX-TTP1-A (aliquot ALCH-ADUX-TTP1-A-2-0-D-A582-36) from ALCHEMIST case ALCH-ADUX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma in situ, NOS; Age at diagnosis: 56.3 years (20,571 days).
Specimen ALCH-ADUX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5522c04a-432a-4459-9868-b9edb002dab9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADUX-NB1-A (Blood Derived Normal), aliquot ALCH-ADUX-NB1-A-1-0-D-A582-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4661fa6-1dfb-4cb9-a907-feead0299ac8

The open-access MAF lists 1,210 somatic variants for this specimen: 809 protein-altering or splice-affecting, 244 silent, 157 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 685, Silent 244, Intron 77, Nonsense Mutation 64, 3'UTR 25, RNA 25, Frame Shift Del 23, Splice Site 21, 5'UTR 14, Splice Region 10, 5'Flank 9, 3'Flank 7.

Variants (750 of 1,210; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.6535G>T p.G2179C | Missense Mutation (SNP) | VAF 31/325 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV70044733; called by muse, mutect2
- ABCA5 | c.1491G>C p.L497F | Missense Mutation (SNP) | VAF 61/534 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67016903; called by muse, mutect2, varscan2
- ABCA9 | c.1948C>A p.P650T | Missense Mutation (SNP) | VAF 54/406 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1387051532; called by muse, mutect2, varscan2
- AC090517.4 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 66/680 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.562); catalogued as rs1458161862; called by muse, mutect2
- ADAM23 | c.1793G>C p.R598P | Missense Mutation (SNP) | VAF 40/425 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100009148; called by muse, mutect2
- ADCY1 | c.2237G>T p.R746L | Missense Mutation (SNP) | VAF 25/240 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as COSV52037928; called by muse, mutect2, varscan2
- ADGRB3 | c.2243C>A p.P748Q | Missense Mutation (SNP) | VAF 38/410 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.449); catalogued as COSV101000316; called by muse, mutect2
- ADGRB3 | c.2489C>A p.S830Y | Missense Mutation (SNP) | VAF 36/375 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.054); catalogued as rs767610095; called by muse, mutect2
- ADGRG4 | c.3256C>T p.R1086C | Missense Mutation (SNP) | VAF 28/186 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs866052593, COSV54949311; called by muse, mutect2, varscan2
- ADGRL2 | c.1989G>A p.M663I (on ENST00000370717 / NM_001366005.1; = p.M650I on NM_012302.4) | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as rs758446671; called by muse, varscan2
- ADGRL3 | c.1132G>T p.A378S (on ENST00000506720 / NM_001322402.2; = p.A310S on NM_015236.6) | Missense Mutation (SNP) | VAF 38/505 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72269154; called by muse, mutect2
- AGBL5 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 22/307 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs150831853; called by muse, mutect2
- ANKEF1 | c.650A>G p.D217G | Missense Mutation (SNP) | VAF 14/459 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as rs1385274506; called by muse, mutect2
- ANKRD18B | c.1699C>T p.R567* | Nonsense Mutation (SNP) | VAF 22/496 reads (4%) | catalogued as rs1157623873, COSV99340463; called by muse, mutect2
- APOB | c.4274C>A p.S1425Y | Missense Mutation (SNP) | VAF 38/306 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as rs767810570; called by muse, mutect2, varscan2
- AQP10 | c.571C>A p.P191T | Missense Mutation (SNP) | VAF 24/229 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100270615; called by muse, mutect2
- ARFGAP3 | c.687del p.G230Efs*26 | Frame Shift Del (DEL) | VAF 18/195 reads (9%) | catalogued as rs754931118; called by mutect2, pindel
- ARHGEF4 | c.1195G>T p.V399L | Missense Mutation (SNP) | VAF 25/261 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.042); catalogued as COSV58123311; called by muse, mutect2
- ARHGEF5 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 107/2228 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.013); catalogued as rs751636255, COSV50211397; called by muse, mutect2
- ARL13B | c.658G>A p.A220T (on ENST00000394222 / NM_001174150.2; = p.A113T on NM_144996.4) | Missense Mutation (SNP) | VAF 42/717 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as rs1187107186; called by muse, mutect2
- ARMCX5 | c.440G>T p.G147V | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.159); catalogued as rs780559667; called by muse, mutect2, varscan2
- ATF3 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 22/432 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1226448270, COSV54235533; called by muse, mutect2
- ATR | c.2725A>T p.T909S | Missense Mutation (SNP) | VAF 47/412 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.083); catalogued as COSV63384724; called by muse, mutect2, varscan2
- B3GNT2 | c.817G>T p.G273C | Missense Mutation (SNP) | VAF 26/518 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57345999; called by muse, mutect2
- BEND4 | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.845); catalogued as COSV72469545; called by muse, mutect2
- BMS1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 38/465 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.811); catalogued as rs763463745; called by muse, mutect2
- BMS1 | c.1286G>A p.R429Q | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs145596198, COSV99080959; called by muse, mutect2
- BPNT1 | c.738G>T p.W246C | Missense Mutation (SNP) | VAF 15/380 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59039490; called by muse, mutect2
- C8orf58 | c.200G>C p.R67P | Missense Mutation (SNP) | VAF 31/281 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.619); catalogued as COSV51516438; called by muse, mutect2, varscan2
- CACNA1D | c.2974del p.L992Sfs*28 (on ENST00000350061 / NM_001128840.3; = p.L1012Sfs*28 on NM_000720.4) | Frame Shift Del (DEL) | VAF 41/450 reads (9%) | catalogued as COSV55464587; called by mutect2, pindel
- CALB1 | c.422C>A p.T141K | Missense Mutation (SNP) | VAF 56/490 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs1232776036; called by muse, mutect2, varscan2
- CAPN12 | c.1955C>T p.A652V | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs747918974; called by muse, mutect2, varscan2
- CASR | c.2486C>T p.T829M (on ENST00000490131; = p.T906M on NM_000388.4) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.013); catalogued as rs200357435; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CBX7 | c.393G>T p.L131F | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.125); catalogued as rs1420650349; called by muse, mutect2, varscan2
- CCT8L2 | c.1031C>A p.P344Q | Missense Mutation (SNP) | VAF 28/300 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.105); catalogued as COSV100742575; called by muse, mutect2
- CDH12 | c.1360C>T p.Q454* | Nonsense Mutation (SNP) | VAF 25/500 reads (5%) | catalogued as COSV101202436; called by muse, mutect2
- CDH12 | c.377C>T p.T126I | Missense Mutation (SNP) | VAF 118/976 reads (12%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.995); catalogued as rs773784194; called by muse, mutect2, varscan2
- CDH18 | c.1160C>A p.S387Y | Missense Mutation (SNP) | VAF 112/957 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56940558; called by muse, mutect2, varscan2
- CDH6 | c.460G>T p.D154Y | Missense Mutation (SNP) | VAF 56/369 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54068397; called by muse, mutect2, varscan2
- CDK14 | c.1291G>T p.D431Y (on ENST00000380050 / NM_001287135.2; = p.D413Y on NM_012395.3) | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV56031769; called by muse, varscan2
- CEACAM20 | c.1132G>T p.E378* | Nonsense Mutation (SNP) | VAF 42/272 reads (15%) | catalogued as COSV57602225; called by muse, mutect2, varscan2
- CELF3 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1369926945, COSV51885599; called by muse, mutect2
- CFTR | c.1656A>C p.Q552H | Missense Mutation (SNP) | VAF 87/892 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as CD993889; called by muse, mutect2
- CHGB | c.1825C>A p.Q609K | Missense Mutation (SNP) | VAF 38/345 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.763); catalogued as COSV100973048; called by muse, mutect2, varscan2
- CLSTN2 | c.2809G>T p.G937W | Missense Mutation (SNP) | VAF 38/412 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as COSV99070550; called by muse, mutect2
- CMTR2 | c.2155C>T p.Q719* | Nonsense Mutation (SNP) | VAF 60/420 reads (14%) | catalogued as COSV100579104; called by muse, mutect2, varscan2
- CNGB3 | c.2273C>G p.A758G | Missense Mutation (SNP) | VAF 135/638 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.118); catalogued as COSV60690349; called by muse, mutect2, varscan2
- CNR2 | c.318C>A p.F106L | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV65694710; called by muse, mutect2
- COL19A1 | c.2065G>T p.G689C | Missense Mutation (SNP) | VAF 89/590 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs780077270; called by muse, mutect2, varscan2
- CREBBP | c.4438G>T p.D1480Y | Missense Mutation (SNP) | VAF 27/392 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52115176; called by muse, mutect2
- CSMD3 | c.10549A>G p.T3517A (on ENST00000297405 / NM_001363185.1; = p.T3348A on NM_052900.3) | Missense Mutation (SNP) | VAF 93/1161 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.113); catalogued as rs917784689; called by muse, mutect2
- CSMD3 | c.2459G>T p.R820L (on ENST00000297405 / NM_001363185.1; = p.R716L on NM_052900.3) | Missense Mutation (SNP) | VAF 22/456 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52328384; called by muse, mutect2
- CYP24A1 | c.1092G>T p.Q364H | Missense Mutation (SNP) | VAF 78/861 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); catalogued as COSV53774975; called by muse, mutect2
- DBX2 | c.76C>A p.P26T | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV60338928; called by muse, mutect2, varscan2
- DGCR8 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as rs1385585441, COSV61226121; called by muse, mutect2, varscan2
- DGKZ | c.791C>A p.P264Q (on ENST00000454345 / NM_001105540.2; = p.P75Q on NM_003646.4) | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs749509532, COSV58984200; called by muse, mutect2, varscan2
- DHX33 | c.1621C>T p.R541W | Missense Mutation (SNP) | VAF 40/411 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs767542929, COSV99834279; called by muse, mutect2, varscan2
- DIRAS2 | c.371A>T p.D124V | Missense Mutation (SNP) | VAF 44/336 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101005818; called by muse, mutect2, varscan2
- DKKL1 | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs756217539; called by muse, mutect2, varscan2
- DNAH11 | c.5128A>G p.M1710V | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs1393818117, COSV100180289; called by muse, mutect2, varscan2
- DNMT3A | c.1111G>T p.E371* | Nonsense Mutation (SNP) | VAF 11/139 reads (8%) | catalogued as rs1290621612, COSV99262859; called by muse, mutect2
- DPYS | c.166G>A p.G56S | Missense Mutation (SNP) | VAF 11/221 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.152); catalogued as rs1373451792; called by muse, mutect2
- DST | c.4628G>T p.G1543V (on ENST00000361203 / NM_001374722.1; = p.G1217V on NM_015548.5) | Missense Mutation (SNP) | VAF 72/532 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.442); catalogued as COSV55018520; called by muse, mutect2, varscan2
- DUOX1 | c.2968A>G p.M990V | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1398327560; called by muse, mutect2, varscan2
- ECD | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 38/968 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV61968028; called by muse, mutect2
- EFCAB6 | c.472A>T p.T158S | Missense Mutation (SNP) | VAF 30/396 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.194); catalogued as rs753629651; called by muse, mutect2
- ELAVL3 | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0.078); catalogued as COSV63645769; called by muse, mutect2
- EPHA3 | c.2950T>G p.*984Eext*51 | Nonstop Mutation (SNP) | VAF 26/258 reads (10%) | catalogued as COSV60698594; called by muse, mutect2
- EPHB4 | c.892G>T p.G298* | Nonsense Mutation (SNP) | VAF 17/146 reads (12%) | catalogued as COSV100639514; called by muse, mutect2, varscan2
- EPPK1 | c.5710G>T p.V1904L | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as rs782239162, COSV73262476; called by muse, mutect2, varscan2
- ERICH3 | c.1399G>T p.E467* | Nonsense Mutation (SNP) | VAF 26/450 reads (6%) | catalogued as COSV58609254; called by muse, mutect2
- ERVV-2 | c.886T>A p.C296S | Missense Mutation (SNP) | VAF 54/302 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs754754165; called by muse, mutect2, varscan2
- EYA1 | c.76G>C p.G26R | Missense Mutation (SNP) | VAF 117/945 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.392); catalogued as COSV100380424, COSV58177967; called by muse, mutect2, varscan2
- F8 | c.2128G>T p.G710W | Missense Mutation (SNP) | VAF 66/281 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM010858, CM1510596; called by muse, mutect2, varscan2
- FAM171A2 | c.1822C>A p.R608S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.447); catalogued as rs1468077016; called by muse, mutect2
- FAM171B | c.1720A>G p.M574V | Missense Mutation (SNP) | VAF 67/612 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs769554315; called by muse, mutect2
- FAT4 | c.9979C>T p.R3327C | Missense Mutation (SNP) | VAF 46/596 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs767411960; called by muse, mutect2
- FMN2 | c.2244del p.T749Rfs*7 | Frame Shift Del (DEL) | VAF 28/246 reads (11%) | catalogued as COSV60415573; called by mutect2, varscan2
- G6PC3 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.899); catalogued as rs145779116; called by muse, mutect2, varscan2
- GAL3ST2 | c.646G>T p.E216* | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | catalogued as COSV51950119; called by muse, varscan2
- GET1-SH3BGR | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 35/283 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.675); catalogued as rs977267568; called by muse, mutect2, varscan2
- GJD2 | c.394G>T p.G132C | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.339); catalogued as rs1354116514; called by muse, mutect2, varscan2
- GRIN2A | c.3862C>A p.R1288S | Missense Mutation (SNP) | VAF 103/1029 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58024367; called by muse, mutect2, varscan2
- GRM8 | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 62/784 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs143468706; called by muse, mutect2
- GSTA2 | c.499G>T p.V167L | Missense Mutation (SNP) | VAF 36/556 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.018); catalogued as COSV101534039; called by muse, mutect2
- HKDC1 | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); catalogued as COSV63578146; called by muse, mutect2
- HOXA3 | c.656C>A p.P219Q | Missense Mutation (SNP) | VAF 15/202 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs1381290384, COSV57827313; called by muse, mutect2
- IFNLR1 | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1452903506, COSV59525918; called by muse, mutect2, varscan2
- IGKV2-30 | c.343C>A p.Q115K | Missense Mutation (SNP) | VAF 40/410 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as rs1235111905; called by muse, mutect2, varscan2
- IGSF3 | c.3057G>C p.E1019D (on ENST00000369486 / NM_001007237.3; = p.E1039D on NM_001542.4) | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs569343519, COSV59585272; called by muse, varscan2
- IMPG1 | c.489C>A p.F163L | Missense Mutation (SNP) | VAF 54/444 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV100886433; called by muse, mutect2, varscan2
- IRAG1 | c.2224C>T p.P742S | Missense Mutation (SNP) | VAF 34/655 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.721); catalogued as rs1292838391; called by muse, mutect2
- ITGA3 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV99144260; called by muse, varscan2
- ITGB8 | c.*5del | Frame Shift Del (DEL) | VAF 22/222 reads (10%) | catalogued as rs770665724; called by mutect2, pindel
- JADE1 | c.82C>T p.R28* | Nonsense Mutation (SNP) | VAF 37/465 reads (8%) | catalogued as COSV56905095; called by muse, mutect2
- JUN | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | catalogued as COSV64664188, COSV64664376; called by mutect2, varscan2
- KAT6B | c.172G>T p.G58C | Missense Mutation (SNP) | VAF 76/698 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99767600; called by muse, mutect2, varscan2
- KIF13A | c.3793G>T p.A1265S | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.038); catalogued as COSV99434666; called by muse, mutect2, varscan2
- KIF2B | c.1060G>A p.G354R | Missense Mutation (SNP) | VAF 39/346 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.134); catalogued as rs200029582; called by muse, mutect2, varscan2
- KIF5A | c.2803C>T p.P935S | Missense Mutation (SNP) | VAF 34/478 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs764612223; ClinVar: uncertain significance; called by muse, mutect2
- KMT2A | c.8810G>C p.R2937P | Missense Mutation (SNP) | VAF 40/612 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV63295587; called by muse, mutect2
- KRTAP20-1 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 42/381 reads (11%) | PolyPhen probably damaging (0.979); catalogued as rs1251164327; called by muse, mutect2, varscan2
- LMBRD1 | c.686C>T p.A229V (on ENST00000649011; = p.A207V on NM_018368.4) | Missense Mutation (SNP) | VAF 110/1354 reads (8%) | SIFT tolerated (0.5); PolyPhen benign (0.138); catalogued as rs746499679; called by muse, mutect2
- LRRC27 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 20/263 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764185972, COSV59810280; called by muse, mutect2
- MAD2L1BP | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs765349395; called by muse, mutect2, varscan2
- MAGEB6 | c.572G>A p.S191N | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.035); catalogued as COSV66872172; called by muse, mutect2, varscan2
- MAGEL2 | c.2882C>T p.P961L | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58569136; called by muse, mutect2
- MATK | c.1508G>A p.R503Q (on ENST00000310132 / NM_139355.3; = p.R504Q on NM_002378.4) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.028); catalogued as rs778726488, COSV59556223; called by mutect2, varscan2
- MMD2 | c.586C>A p.P196T (on ENST00000404774 / NM_001100600.2; = p.P172T on NM_198403.4) | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764826554; called by mutect2, varscan2
- MPEG1 | c.1916G>A p.R639Q | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.302); catalogued as rs773612654, COSV57088136; called by muse, mutect2
- MRGPRX2 | c.955C>A p.Q319K | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.421); catalogued as COSV100316589; called by muse, varscan2
- MSH2 | c.2692G>T p.E898* | Nonsense Mutation (SNP) | VAF 72/617 reads (12%) | catalogued as COSV51884351; called by muse, mutect2, varscan2
- MT1A | c.53C>A p.S18Y | Missense Mutation (SNP) | VAF 33/309 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV99319236; called by muse, mutect2, varscan2
- MUC12 | c.2816C>A p.T939K (on ENST00000379442; = p.T796K on NM_001164462.1) | Missense Mutation (SNP) | VAF 46/1232 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.413); catalogued as COSV65194737; called by muse, mutect2
- MUC16 | c.31397C>A p.T10466K | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs772403448; called by muse, mutect2, varscan2
- MYH4 | c.653C>T p.T218I | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as rs773942589; called by muse, mutect2, varscan2
- MYH7 | c.5027G>A p.R1676Q | Missense Mutation (SNP) | VAF 48/461 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.948); catalogued as rs1451176863; ClinVar: uncertain significance; called by muse, varscan2
- MYO18A | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 27/284 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757381434; called by muse, mutect2
- MYO7A | c.6279G>C p.K2093N | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.148); catalogued as COSV60022937; called by muse, mutect2
- MYO7A | c.6415A>T p.S2139C | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.249); catalogued as COSV60020135; called by muse, mutect2, varscan2
- MZF1 | c.2077C>T p.R693W | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs1223356883; called by muse, mutect2
- NAA11 | c.382T>A p.F128I | Missense Mutation (SNP) | VAF 22/422 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54514809; called by muse, mutect2
- NAAA | c.767G>T p.R256L | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.055); catalogued as rs1388381303, COSV54431426; called by muse, mutect2, varscan2
- NAV3 | c.4888C>A p.L1630I | Missense Mutation (SNP) | VAF 42/297 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV57096080; called by muse, mutect2, varscan2
- NBEAL1 | c.5824C>T p.H1942Y | Missense Mutation (SNP) | VAF 22/297 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV68915828; called by muse, mutect2
- NCKIPSD | c.1370G>A p.R457Q | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs1179604806; called by muse, mutect2
- NEB | c.1152+1G>C p.X384_splice | Splice Site (SNP) | VAF 43/596 reads (7%) | catalogued as CS116375, CS134827, COSV51438040; called by muse, mutect2
- NEU1 | c.982G>T p.G328C | Missense Mutation (SNP) | VAF 24/421 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM000767, COSV57668656; called by muse, mutect2
- NEUROD4 | c.413C>A p.A138D | Missense Mutation (SNP) | VAF 38/415 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV54470799, COSV54472887; called by muse, mutect2
- NEXMIF | c.3650G>C p.R1217P | Missense Mutation (SNP) | VAF 31/260 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV50028941; called by muse, mutect2, varscan2
- NF1 | c.1783G>T p.E595* | Nonsense Mutation (SNP) | VAF 78/912 reads (9%) | catalogued as CD1311319, CM1111789, CM1311457, COSV62204483; called by muse, mutect2
- NFASC | c.757G>T p.A253S (on ENST00000339876 / NM_001378329.1; = p.A264S on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV58373975, COSV99046033; called by muse, mutect2, varscan2
- NLRP10 | c.718C>A p.Q240K | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.038); catalogued as COSV60782837; called by muse, mutect2, varscan2
- NLRP12 | c.912C>A p.H304Q | Missense Mutation (SNP) | VAF 24/267 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV60751435, COSV60755610; called by muse, mutect2
- NLRP14 | c.1619G>T p.R540L | Missense Mutation (SNP) | VAF 120/941 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs142485585, COSV99079086; called by muse, mutect2, varscan2
- NOTCH3 | c.6854G>T p.G2285V | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.199); catalogued as COSV54638476; called by muse, mutect2, varscan2
- NPAP1 | c.2380A>T p.S794C | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.706); catalogued as COSV61507799; called by muse, mutect2, varscan2
- NRG2 | c.391G>T p.V131L | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.202); catalogued as rs1197921422; called by muse, mutect2, varscan2
- NTRK2 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 40/1064 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1194284331, COSV52869584; called by muse, mutect2
- NYAP1 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.022); catalogued as rs368554898, COSV55718797; called by mutect2, varscan2
- OGDH | c.2014C>T p.R672W | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766790731; called by muse, mutect2
- OR10Q1 | c.182C>A p.T61N | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs777067286; called by muse, varscan2
- OR13F1 | c.719C>A p.T240K | Missense Mutation (SNP) | VAF 50/418 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100594789; called by muse, mutect2, varscan2
- OR1C1 | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 51/267 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.357); catalogued as COSV68715860; called by muse, mutect2, varscan2
- OR2J3 | c.524G>C p.R175P | Missense Mutation (SNP) | VAF 64/576 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV65848879; called by muse, mutect2, varscan2
- OR4A16 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 43/514 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.698); catalogued as rs144365049; called by muse, mutect2
- OR52E8 | c.662T>A p.L221H | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV66205111; called by muse, mutect2, varscan2
- OR5D18 | c.812C>A p.T271K | Missense Mutation (SNP) | VAF 45/398 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.392); catalogued as COSV61736614; called by muse, mutect2, varscan2
- OR5H1 | c.937T>C p.Y313H | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1033593914, COSV100641710; called by muse, mutect2
- OR5H15 | c.823C>A p.P275T | Missense Mutation (SNP) | VAF 70/842 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV62948594; called by muse, mutect2
- OR5M10 | c.504C>A p.F168L | Missense Mutation (SNP) | VAF 33/315 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV73242248; called by muse, mutect2, varscan2
- OR6Y1 | c.947G>A p.G316E | Missense Mutation (SNP) | VAF 46/198 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV56930308; called by muse, varscan2
- OR8B8 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 29/283 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV60143767, COSV60145573; called by muse, mutect2, varscan2
- PARD6B | c.1083del p.K361Nfs*3 | Frame Shift Del (DEL) | VAF 24/180 reads (13%) | catalogued as COSV99056604; called by mutect2, pindel
- PAX6 | c.241C>A p.P81T | Missense Mutation (SNP) | VAF 88/946 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.149); catalogued as CD156508; called by muse, mutect2
- PCDH8 | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs759814135, COSV58813687; called by mutect2, varscan2
- PCDHA10 | c.1166C>T p.T389M | Missense Mutation (SNP) | VAF 40/389 reads (10%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.16); catalogued as rs193920994, COSV56487682; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHA2 | c.1982C>T p.A661V | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.25); catalogued as rs372284917; called by muse, mutect2, varscan2
- PCDHAC1 | c.1805G>T p.R602L | Missense Mutation (SNP) | VAF 42/285 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV99166205, COSV99166522, COSV99169367; called by muse, mutect2, varscan2
- PCDHB9 | c.1219G>T p.G407C | Missense Mutation (SNP) | VAF 164/707 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53384419, COSV53384952; called by muse, mutect2, varscan2
- PCDHGB1 | c.185G>T p.R62L | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53959666; called by muse, mutect2, varscan2
- PCSK9 | c.151G>A p.G51S | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as rs1346757467; called by muse, varscan2
- PDE4DIP | c.875G>T p.S292I | Missense Mutation (SNP) | VAF 16/380 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100519018; called by muse, mutect2
- PEDS1-UBE2V1 | c.1046G>T p.R349L | Missense Mutation (SNP) | VAF 60/786 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.733); catalogued as COSV59016548; called by muse, mutect2
- PIGO | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 39/355 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs763191841, COSV53055565; called by muse, mutect2, varscan2
- PPP2R1B | c.520G>T p.V174F | Missense Mutation (SNP) | VAF 37/329 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV59535504; called by muse, mutect2, varscan2
- PPP6R1 | c.1102G>T p.A368S | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as COSV69799451; called by muse, mutect2, varscan2
- PRDM9 | c.547C>A p.L183M | Missense Mutation (SNP) | VAF 113/1094 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99690637; called by muse, mutect2
- PRPF40A | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 32/486 reads (7%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.05); catalogued as rs1437762835; called by muse, mutect2
- PRTFDC1 | c.175G>T p.D59Y | Missense Mutation (SNP) | VAF 12/179 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.744); catalogued as COSV60777359; called by muse, mutect2
- PSG6 | c.899C>G p.T300R | Missense Mutation (SNP) | VAF 95/773 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs750179815, COSV51834910; called by muse, mutect2, varscan2
- PSG8 | c.641C>G p.P214R | Missense Mutation (SNP) | VAF 40/356 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1217784155, COSV60617294; called by muse, varscan2
- PYCR3 | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs142512194; called by muse, mutect2, varscan2
- QSER1 | c.3144G>T p.M1048I (on ENST00000399302; = p.M1177I on NM_001076786.3) | Missense Mutation (SNP) | VAF 45/341 reads (13%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs776302648; called by muse, mutect2, varscan2
- RABGAP1L | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 36/352 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs534755457; called by muse, mutect2, varscan2
- RASAL2 | c.2546C>T p.T849M | Missense Mutation (SNP) | VAF 77/561 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.911); catalogued as rs150729197; called by muse, mutect2, varscan2
- RB1 | c.2527G>T p.E843* | Nonsense Mutation (SNP) | VAF 87/665 reads (13%) | catalogued as COSV57317561; called by muse, mutect2, varscan2
- RBFOX1 | c.758-1G>T p.X253_splice | Splice Site (SNP) | VAF 20/144 reads (14%) | catalogued as COSV60963104; called by muse, varscan2
- RETREG2 | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 11/85 reads (13%) | catalogued as COSV99065856; called by muse, mutect2, varscan2
- RHAG | c.1003G>T p.G335C | Missense Mutation (SNP) | VAF 67/1015 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57706500, COSV57706736; called by muse, mutect2
- RIBC1 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV99394927; called by muse, mutect2, varscan2
- RNF187 | c.105C>A p.C35* | Nonsense Mutation (SNP) | VAF 7/55 reads (13%) | catalogued as rs956109156; called by muse, mutect2, varscan2
- RNF220 | c.1606G>C p.E536Q | Missense Mutation (SNP) | VAF 16/185 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59190140; called by muse, mutect2
- ROBO2 | c.2075C>A p.P692Q | Missense Mutation (SNP) | VAF 59/620 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV59895917; called by muse, mutect2
- RSPH6A | c.773C>T p.T258M | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.176); catalogued as rs755304600, COSV55573331; called by muse, mutect2, varscan2
- RXRG | c.181dup p.T61Nfs*76 | Frame Shift Ins (INS) | VAF 21/139 reads (15%) | catalogued as COSV63232364; called by mutect2, pindel, varscan2
- RYR2 | c.6865G>C p.G2289R | Missense Mutation (SNP) | VAF 118/723 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63664975; called by muse, mutect2, varscan2
- RYR2 | c.14528G>T p.R4843L | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63676917; called by muse, mutect2
- SEMA5B | c.2528G>A p.R843H | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV52102450; called by muse, mutect2, varscan2
- SEMA6A | c.2258C>T p.T753M | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as rs1561459244, COSV56713134; called by muse, mutect2, varscan2
- SEPTIN9 | c.1379G>C p.R460P (on ENST00000427177 / NM_001113491.2; = p.R442P on NM_006640.4) | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100218767; called by muse, mutect2
- SHANK2 | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.996); catalogued as COSV58345461; called by muse, mutect2, varscan2
- SHISA7 | c.1078G>T p.G360C | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV66244560; called by muse, mutect2, varscan2
- SHROOM3 | c.2026A>G p.S676G | Missense Mutation (SNP) | VAF 12/185 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99935469; called by muse, mutect2
- SI | c.1656G>C p.W552C | Missense Mutation (SNP) | VAF 77/660 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs1415993217, COSV52278400, COSV52295798; called by muse, mutect2, varscan2
- SIGLEC12 | c.784G>T p.D262Y (on ENST00000291707 / NM_053003.4; = p.D144Y on NM_033329.2) | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.116); catalogued as rs1262955207; called by muse, varscan2
- SIGLECL1 | c.122T>C p.M41T | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.236); catalogued as rs1489598090; called by muse, mutect2, varscan2
- SLC1A1 | c.563T>C p.M188T | Missense Mutation (SNP) | VAF 39/626 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs374636530; called by muse, mutect2
- SLC1A6 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as COSV55672052; called by muse, mutect2
- SLC25A19 | c.431C>T p.T144I | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs776470458; called by muse, mutect2, varscan2
- SLC6A19 | c.1619T>C p.L540P | Missense Mutation (SNP) | VAF 25/253 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs971321082, COSV57250769; called by muse, mutect2
- SLC6A4 | c.52G>T p.G18* | Nonsense Mutation (SNP) | VAF 70/780 reads (9%) | catalogued as COSV55565480; called by muse, mutect2
- SMC1B | c.1561G>C p.D521H | Missense Mutation (SNP) | VAF 59/654 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs760374235, COSV62529656; called by muse, mutect2
- SMOC1 | c.1292-1G>A p.X431_splice | Splice Site (SNP) | VAF 26/306 reads (8%) | catalogued as COSV100734395; called by muse, mutect2
- SOGA1 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.737); catalogued as rs1209772687; called by muse, mutect2, varscan2
- SPATA18 | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 15/364 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.653); catalogued as rs999831483; called by muse, mutect2
- SPEG | c.6469G>T p.G2157W | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV100405584; called by muse, varscan2
- SPEG | c.6470G>T p.G2157V | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.188); catalogued as COSV56673943; called by muse, mutect2, varscan2
- SPTA1 | c.6676G>A p.A2226T | Missense Mutation (SNP) | VAF 60/666 reads (9%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.679); catalogued as rs766070401, COSV63749098, COSV63750709; called by muse, mutect2
- SPTAN1 | c.4076G>T p.R1359L | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.107); catalogued as COSV63987184; called by muse, mutect2
- SPTBN5 | c.4217G>A p.R1406H | Missense Mutation (SNP) | VAF 18/220 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs745827743; called by muse, mutect2
- STYXL2 | c.1168G>T p.E390* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV54810084; called by muse, mutect2, varscan2
- SVIL | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 29/263 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.023); catalogued as rs143104241; called by muse, mutect2, varscan2
- SYN2 | c.1625C>A p.S542Y | Missense Mutation (SNP) | VAF 36/394 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs754831383; called by muse, mutect2
- TACC2 | c.7798G>A p.A2600T (on ENST00000334433; = p.A678T on NM_006997.4) | Missense Mutation (SNP) | VAF 27/259 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.776); catalogued as COSV53279475; called by muse, mutect2, varscan2
- TAS2R41 | c.172C>A p.L58M | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV68765306; called by muse, mutect2, varscan2
- TAS2R60 | c.297G>T p.Q99H | Missense Mutation (SNP) | VAF 67/573 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.013); catalogued as COSV100223703; called by muse, mutect2, varscan2
- TGFB1I1 | c.649C>T p.R217C (on ENST00000394863 / NM_001042454.3; = p.R200C on NM_015927.4) | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs754603348; called by muse, mutect2
- TGM1 | c.281G>T p.G94V | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.168); catalogued as CM014103; called by muse, mutect2, varscan2
- THAP12 | c.526A>G p.M176V | Missense Mutation (SNP) | VAF 11/217 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.096); catalogued as COSV52612550; called by muse, mutect2
- TINAG | c.1135C>A p.Q379K | Missense Mutation (SNP) | VAF 28/404 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs1403579880, COSV99448885; called by muse, mutect2
- TIPRL | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 29/427 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760294386, COSV100893232; called by muse, mutect2
- TMEM229B | c.428G>T p.R143L | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); catalogued as COSV62539244; called by muse, mutect2, varscan2
- TMPRSS11A | c.1185C>A p.N395K | Missense Mutation (SNP) | VAF 23/544 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58360304; called by muse, mutect2
- TMPRSS13 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV101471494, COSV70625863; called by muse, mutect2, varscan2
- TMPRSS15 | c.587C>G p.T196R | Missense Mutation (SNP) | VAF 73/789 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.257); catalogued as COSV99517519; called by muse, mutect2
- TNRC6B | c.3298C>T p.R1100* (on ENST00000454349 / NM_001162501.2; = p.R1047* on NM_015088.3) | Nonsense Mutation (SNP) | VAF 20/376 reads (5%) | catalogued as COSV57288112; called by muse, mutect2
- TOB2 | c.10G>T p.E4* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV59501418; called by muse, varscan2
- TOM1 | c.1279G>A p.D427N | Missense Mutation (SNP) | VAF 15/189 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV65897416; called by muse, mutect2
- TPCN2 | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778119558, COSV53727842; called by muse, mutect2, varscan2
- TPO | c.19C>A p.L7M | Missense Mutation (SNP) | VAF 74/856 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.123); catalogued as COSV61098614; called by muse, mutect2
- TPRX1 | c.988C>G p.P330A | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs763057221, COSV59115147; called by mutect2, varscan2
- TRPC3 | c.1589G>C p.W530S (on ENST00000379645 / NM_001366479.2; = p.W457S on NM_003305.2) | Missense Mutation (SNP) | VAF 25/367 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53374934; called by muse, mutect2
- TRPC4 | c.2684G>A p.G895D (on ENST00000379705 / NM_016179.4; = p.G900D on NM_003306.3) | Missense Mutation (SNP) | VAF 71/399 reads (18%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.086); catalogued as rs769331202; called by muse, mutect2, varscan2
- TTC21B | c.3673C>T p.R1225C | Missense Mutation (SNP) | VAF 49/879 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs377393152; called by muse, mutect2
- TTC3 | c.2334del p.E779Kfs*5 | Frame Shift Del (DEL) | VAF 34/272 reads (13%) | catalogued as rs756650873; called by mutect2, varscan2
- TTN | c.69575C>A p.P23192H (on ENST00000591111; = p.P15768H on NM_003319.4) | Missense Mutation (SNP) | VAF 25/405 reads (6%) | PolyPhen probably damaging (0.999); catalogued as COSV100636182; called by muse, mutect2
- TTN | c.7679G>T p.G2560V (on ENST00000591111; = p.G2514V on NM_003319.4) | Missense Mutation (SNP) | VAF 50/689 reads (7%) | PolyPhen possibly damaging (0.896); catalogued as COSV60291312; called by muse, mutect2
- TUBA3C | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 33/208 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as rs201138602; called by muse, mutect2, varscan2
- TWF1 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 57/553 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs751907907; called by muse, mutect2
- UBIAD1 | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 24/530 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1245495523, COSV100954850, COSV65147920; called by muse, mutect2
- UBQLN1 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1257893544; called by muse, mutect2, varscan2
- UGT2B7 | c.1558G>T p.A520S | Missense Mutation (SNP) | VAF 18/402 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as rs1377645447; called by muse, mutect2
- USP44 | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 39/227 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs755556772, COSV51562769; called by muse, mutect2, varscan2
- WDFY4 | c.677C>A p.T226N | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs767327464; called by muse, mutect2
- YTHDF1 | c.1015G>T p.G339W | Missense Mutation (SNP) | VAF 23/164 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100945628; called by muse, mutect2, varscan2
- ZAN | c.1991C>T p.P664L | Missense Mutation (SNP) | VAF 43/261 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV61805874; called by muse, mutect2, varscan2
- ZCCHC14 | c.2021C>T p.T674I (on ENST00000268616; = p.T811I on NM_015144.3) | Missense Mutation (SNP) | VAF 35/217 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1389090688; called by muse, mutect2, varscan2
- ZDHHC23 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 44/611 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs981531807; called by muse, mutect2
- ZDHHC8 | c.2074G>A p.A692T | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1410233066; called by muse, mutect2, varscan2
- ZEB1 | c.328G>A p.D110N | Missense Mutation (SNP) | VAF 28/396 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs757878118; called by muse, mutect2
- ZER1 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.249); catalogued as rs774881908; called by muse, mutect2
- ZIC1 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as rs1422516768; called by muse, mutect2, varscan2
- ZNF230 | c.1274G>A p.C425Y | Missense Mutation (SNP) | VAF 90/939 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200585922; called by muse, mutect2
- ZNF492 | c.1474C>T p.L492F | Missense Mutation (SNP) | VAF 36/374 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.239); catalogued as COSV71761929; called by muse, mutect2, varscan2
- ZNF597 | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as rs1181677149, COSV57085057; called by muse, mutect2
- ZSCAN5A | c.638A>C p.K213T | Missense Mutation (SNP) | VAF 60/518 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV54232818; called by muse, mutect2, varscan2
- AAGAB | c.821-2A>G p.X274_splice | Splice Site (SNP) | VAF 60/549 reads (11%) | called by muse, mutect2, varscan2
- AAR2 | c.1183C>A p.P395T | Missense Mutation (SNP) | VAF 21/160 reads (13%) | PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- ABCF2 | c.1563G>C p.Q521H | Missense Mutation (SNP) | VAF 26/243 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AC005324.2 | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- AC010255.2 | c.262C>A p.R88S | Missense Mutation (SNP) | VAF 42/422 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- AC021660.3 | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 18/237 reads (8%) | called by muse, mutect2
- AC093827.5 | c.256C>T p.L86F | Missense Mutation (SNP) | VAF 28/382 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2
- ACBD5 | c.1319G>T p.G440V (on ENST00000375888 / NM_001352568.1; = p.G431V on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.801); called by muse, mutect2
- ACOT7 | c.940C>T p.P314S (on ENST00000377855 / NM_181864.3; = p.P304S on NM_007274.4) | Missense Mutation (SNP) | VAF 33/246 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ACP3 | c.377dup p.E127Rfs*24 | Frame Shift Ins (INS) | VAF 75/726 reads (10%) | called by mutect2, pindel, varscan2
- ACSL1 | c.1551G>T p.Q517H | Missense Mutation (SNP) | VAF 32/612 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2
- ACTC1 | c.130G>T p.G44* | Nonsense Mutation (SNP) | VAF 24/231 reads (10%) | called by muse, mutect2, varscan2
- ADA | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 50/433 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- ADAM11 | c.2134C>T p.H712Y | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAM18 | c.268A>T p.M90L | Missense Mutation (SNP) | VAF 30/418 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.091); called by muse, mutect2
- ADAM18 | c.1595G>C p.G532A | Missense Mutation (SNP) | VAF 32/574 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.938); called by muse, mutect2
- ADAMTS1 | c.2584G>T p.E862* | Nonsense Mutation (SNP) | VAF 47/641 reads (7%) | called by muse, mutect2
- ADAMTS1 | c.1628G>C p.G543A | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by mutect2, varscan2
- ADAMTS16 | c.2605C>A p.Q869K | Missense Mutation (SNP) | VAF 34/327 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS19 | c.3586C>A p.R1196S | Missense Mutation (SNP) | VAF 34/330 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS20 | c.4995+1G>T p.X1665_splice | Splice Site (SNP) | VAF 16/129 reads (12%) | called by muse, varscan2
- ADAMTSL1 | c.2906C>T p.A969V | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.014); called by muse, mutect2
- ADARB1 | c.1553G>A p.G518E (on ENST00000360697 / NM_001346687.2; = p.G478E on NM_001112.4) | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ADARB1 | c.2113G>T p.A705S (on ENST00000360697 / NM_001346687.2; = p.A665S on NM_001112.4) | Missense Mutation (SNP) | VAF 21/258 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); called by muse, mutect2
- ADGRA1 | c.902G>C p.R301T | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); called by muse, mutect2
- ADGRB3 | c.1906A>T p.I636F | Missense Mutation (SNP) | VAF 23/221 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.602); called by muse, mutect2
- AL121899.2 | c.1940G>T p.C647F | Missense Mutation (SNP) | VAF 30/289 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ALOX5 | c.497G>T p.R166L | Missense Mutation (SNP) | VAF 37/478 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.037); called by muse, mutect2
- ALPG | c.1475C>A p.A492D | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMOT | c.1632T>A p.N544K (on ENST00000371959 / NM_001113490.1; = p.N135K on NM_133265.3) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.255); called by muse, mutect2
- ANK2 | c.6997G>T p.V2333L | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANK3 | c.4034A>T p.Q1345L (on ENST00000280772 / NM_001320874.2; = p.Q479L on NM_001149.3) | Missense Mutation (SNP) | VAF 26/421 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- ANKMY1 | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD13B | c.289G>C p.V97L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0.075); called by muse, mutect2
- ANKRD17 | c.1790G>T p.G597V | Missense Mutation (SNP) | VAF 26/376 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANKRD52 | c.810C>A p.D270E | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ANO6 | c.2062C>A p.P688T | Missense Mutation (SNP) | VAF 75/621 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APBB3 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 24/145 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APCDD1 | c.98G>T p.R33M | Missense Mutation (SNP) | VAF 54/363 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ARHGAP12 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 22/383 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGAP36 | c.1603G>T p.E535* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | called by mutect2, varscan2
- ARID5B | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 56/934 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.039); called by muse, mutect2
- ASPM | c.7627G>A p.G2543R | Missense Mutation (SNP) | VAF 24/589 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); called by muse, mutect2
- ASPM | c.2026G>T p.D676Y | Missense Mutation (SNP) | VAF 38/993 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.041); called by muse, mutect2
- ASPM | c.259C>A p.L87M | Missense Mutation (SNP) | VAF 28/410 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.254); called by muse, mutect2
- ATL3 | c.1039A>G p.T347A | Missense Mutation (SNP) | VAF 18/379 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- ATM | c.2086G>T p.G696* | Nonsense Mutation (SNP) | VAF 66/588 reads (11%) | called by muse, mutect2, varscan2
- ATP11A | c.3338A>T p.Q1113L | Missense Mutation (SNP) | VAF 50/247 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- B3GAT2 | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- BAHCC1 | c.7622G>T p.W2541L | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BAHD1 | c.1870G>T p.E624* | Nonsense Mutation (SNP) | VAF 21/163 reads (13%) | called by muse, mutect2, varscan2
- BARD1 | c.931A>T p.K311* | Nonsense Mutation (SNP) | VAF 29/232 reads (13%) | called by muse, mutect2, varscan2
- BAZ1B | c.1481C>T p.A494V | Missense Mutation (SNP) | VAF 16/327 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.253); called by muse, mutect2
- BCL9 | c.3275T>C p.M1092T | Missense Mutation (SNP) | VAF 27/350 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.262); called by muse, mutect2
- BCR | c.1566G>T p.L522= | Splice Region (SNP) | VAF 21/161 reads (13%) | called by muse, mutect2, varscan2
- BOD1L1 | c.7336G>A p.G2446R | Missense Mutation (SNP) | VAF 32/453 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.125); called by muse, mutect2
- BPTF | c.2905T>A p.S969T | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2
- BRCC3 | c.13G>T p.V5L | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BRD8 | c.2683G>C p.D895H | Missense Mutation (SNP) | VAF 48/512 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); called by muse, mutect2
- C16orf78 | c.54C>A p.Y18* | Nonsense Mutation (SNP) | VAF 43/368 reads (12%) | called by muse, mutect2, varscan2
- C1QC | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 29/198 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- C1QTNF1 | c.166C>A p.Q56K | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C4orf54 | c.1131G>T p.E377D | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); called by muse, mutect2
- C7orf31 | c.1592G>T p.R531I | Missense Mutation (SNP) | VAF 52/639 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.428); called by muse, mutect2
- C7orf31 | c.1591A>T p.R531* | Nonsense Mutation (SNP) | VAF 52/642 reads (8%) | called by muse, mutect2
- C9orf131 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2
- C9orf43 | c.97A>T p.R33W | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CA12 | c.884G>T p.C295F | Missense Mutation (SNP) | VAF 59/441 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA1D | c.3517-2A>T p.X1173_splice (on ENST00000350061 / NM_001128840.3; = p.X1193_splice on NM_000720.4) | Splice Site (SNP) | VAF 43/368 reads (12%) | called by muse, mutect2, varscan2
- CACNG5 | c.305C>A p.P102Q | Missense Mutation (SNP) | VAF 29/216 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CAMKK1 | c.248A>C p.Y83S | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- CARD10 | c.1884G>T p.W628C | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- CC2D1B | c.796G>T p.G266C | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- CCDC112 | c.1179+8G>A | Splice Region (SNP) | VAF 24/492 reads (5%) | called by muse, mutect2
- CCDC114 | c.1898G>C p.G633A | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by mutect2, varscan2
- CCDC175 | c.2196C>A p.D732E | Missense Mutation (SNP) | VAF 59/336 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC40 | c.2655G>T p.K885N | Missense Mutation (SNP) | VAF 36/341 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- CCM2L | c.975C>A p.F325L | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CCT6A | c.764A>T p.E255V | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- CD209 | c.344C>A p.P115Q | Missense Mutation (SNP) | VAF 68/603 reads (11%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CD79B | c.302A>T p.N101I | Missense Mutation (SNP) | VAF 32/424 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2
- CD84 | c.865C>A p.Q289K (on ENST00000311224 / NM_001184879.2; = p.Q272K on NM_003874.4) | Missense Mutation (SNP) | VAF 32/577 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2
- CDC25B | c.1653G>T p.K551N (on ENST00000245960 / NM_021873.3; = p.K537N on NM_004358.4) | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); called by muse, mutect2
- CDCA2 | c.61+7G>A | Splice Region (SNP) | VAF 23/415 reads (6%) | called by muse, mutect2
- CDCA5 | c.265T>A p.Y89N | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.179); called by muse, mutect2
- CDH10 | c.2020A>T p.T674S | Missense Mutation (SNP) | VAF 130/1065 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- CDH11 | c.1450A>G p.N484D | Missense Mutation (SNP) | VAF 38/323 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CDH18 | c.1615C>A p.L539M | Missense Mutation (SNP) | VAF 54/495 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CDHR3 | c.2611C>A p.P871T | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); called by muse, mutect2
- CDK12 | c.4249G>T p.G1417W (on ENST00000447079 / NM_016507.4; = p.G1408W on NM_015083.3) | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); called by mutect2, varscan2
- CDK14 | c.93T>A p.A31= | Splice Region (SNP) | VAF 45/438 reads (10%) | called by muse, mutect2, varscan2
- CDON | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 35/315 reads (11%) | called by muse, mutect2, varscan2
- CDX2 | c.47G>T p.S16I | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); called by muse, mutect2
- CELSR1 | c.2107G>T p.G703W | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP295 | c.1153G>T p.V385F | Missense Mutation (SNP) | VAF 54/402 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.022); called by muse, varscan2
- CEP70 | c.375A>T p.K125N | Missense Mutation (SNP) | VAF 54/431 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CFHR5 | c.1071C>A p.Y357* | Nonsense Mutation (SNP) | VAF 92/689 reads (13%) | called by muse, mutect2, varscan2
- CHD1 | c.4609G>T p.D1537Y | Missense Mutation (SNP) | VAF 65/497 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CHMP3 | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 34/364 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); called by muse, mutect2
- CHRM3 | c.439A>G p.I147V | Missense Mutation (SNP) | VAF 56/353 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CHRNA1 | c.1436A>T p.N479I (on ENST00000261007 / NM_001039523.3; = p.N454I on NM_000079.4) | Missense Mutation (SNP) | VAF 76/756 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, mutect2
- CHRNB4 | c.47G>A p.C16Y | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLEC12A | c.98C>A p.P33Q | Missense Mutation (SNP) | VAF 48/412 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- CLIP1 | c.4228G>T p.G1410C (on ENST00000620786 / NM_001247997.1; = p.G1399C on NM_002956.2) | Missense Mutation (SNP) | VAF 51/403 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLTCL1 | c.1615G>T p.D539Y | Missense Mutation (SNP) | VAF 41/291 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- CNOT3 | c.1960C>G p.P654A | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CNTN3 | c.2380A>G p.T794A | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2
- CNTNAP2 | c.2384-2A>G p.X795_splice | Splice Site (SNP) | VAF 28/735 reads (4%) | called by muse, mutect2
- COL11A1 | c.1792G>A p.G598R | Missense Mutation (SNP) | VAF 47/770 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL11A1 | c.276T>G p.G92= | Splice Region (SNP) | VAF 48/546 reads (9%) | called by muse, mutect2
- COL19A1 | c.715C>A p.Q239K | Missense Mutation (SNP) | VAF 59/472 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- COL19A1 | c.2253G>T p.E751D | Missense Mutation (SNP) | VAF 20/456 reads (4%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.682); called by muse, mutect2
- COL25A1 | c.449G>T p.G150V | Missense Mutation (SNP) | VAF 13/259 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL5A1 | c.307C>A p.L103I | Missense Mutation (SNP) | VAF 28/430 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.401); called by muse, mutect2
- COL6A5 | c.1426C>G p.P476A | Missense Mutation (SNP) | VAF 42/680 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2
- COL6A6 | c.1287T>A p.C429* | Nonsense Mutation (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2
- COL7A1 | c.6979G>A p.G2327R | Missense Mutation (SNP) | VAF 11/283 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL9A2 | c.848G>A p.G283D | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COQ2 | c.570G>T p.K190N | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); called by muse, mutect2
- CPXM2 | c.1848C>A p.Y616* | Nonsense Mutation (SNP) | VAF 24/279 reads (9%) | called by muse, mutect2
- CRYBB2 | c.311G>T p.S104I | Missense Mutation (SNP) | VAF 26/484 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.092); called by muse, mutect2
- CRYBG3 | c.6805G>C p.V2269L | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.03); called by muse, mutect2
- CSF1R | c.1918C>A p.L640M | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSPG5 | c.1507G>C p.A503P | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.93); called by muse, mutect2
- CST9L | c.195C>A p.Y65* | Nonsense Mutation (SNP) | VAF 41/285 reads (14%) | called by muse, mutect2, varscan2
- CTSE | c.687A>T p.E229D (on ENST00000360218; = p.E224D on NM_001910.4) | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT tolerated (0.92); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CUL2 | c.1056G>T p.Q352H | Missense Mutation (SNP) | VAF 27/614 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2
- CYP2R1 | c.1001G>C p.G334A | Missense Mutation (SNP) | VAF 47/528 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2
- CYP7B1 | c.588A>G p.I196M | Missense Mutation (SNP) | VAF 107/796 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- DBH | c.538C>A p.L180M | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- DCAF1 | c.3070G>A p.A1024T | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.033); called by muse, mutect2
- DDR2 | c.2092A>T p.M698L | Missense Mutation (SNP) | VAF 127/723 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DES | c.102_117del p.F35Sfs*10 | Frame Shift Del (DEL) | VAF 3/24 reads (13%) | called by mutect2, pindel
- DHX34 | c.2279del p.P760Qfs*12 | Frame Shift Del (DEL) | VAF 6/45 reads (13%) | called by mutect2, varscan2
- DHX9 | c.1996A>T p.M666L | Missense Mutation (SNP) | VAF 86/520 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DIS3L2 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 31/474 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.013); called by muse, mutect2
- DISP1 | c.2966G>A p.G989E | Missense Mutation (SNP) | VAF 41/830 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- DISP3 | c.1008del p.S337Afs*4 | Frame Shift Del (DEL) | VAF 10/86 reads (12%) | called by mutect2, pindel, varscan2
- DNAH10 | c.6828C>A p.N2276K (on ENST00000409039; = p.N2215K on NM_207437.3) | Missense Mutation (SNP) | VAF 30/285 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH11 | c.1163T>A p.L388* | Nonsense Mutation (SNP) | VAF 36/318 reads (11%) | called by muse, mutect2, varscan2
- DNAH11 | c.5810A>G p.Q1937R | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH14 | c.6179G>A p.G2060E (on ENST00000445597; = p.G2713E on NM_001367479.1) | Missense Mutation (SNP) | VAF 17/260 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH17 | c.3646G>T p.E1216* | Nonsense Mutation (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- DNAJA4 | c.815G>T p.C272F (on ENST00000343789; = p.C301F on NM_018602.3) | Missense Mutation (SNP) | VAF 24/389 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- DNAJC13 | c.268A>T p.R90* | Nonsense Mutation (SNP) | VAF 32/336 reads (10%) | called by muse, mutect2
- DNMT3A | c.1635G>T p.E545D | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2
- DOCK11 | c.3579G>T p.M1193I | Missense Mutation (SNP) | VAF 23/148 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK8 | c.4498G>T p.E1500* | Nonsense Mutation (SNP) | VAF 24/336 reads (7%) | called by muse, mutect2
- DOCK9 | c.5336G>A p.G1779E (on ENST00000376460 / NM_001366676.2; = p.G1780E on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/239 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- DOHH | c.787G>T p.D263Y | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.251); called by muse, mutect2
- DSPP | c.3660C>G p.S1220R | Missense Mutation (SNP) | VAF 41/786 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.667); called by muse, mutect2
- DST | c.6599G>T p.C2200F | Missense Mutation (SNP) | VAF 44/556 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.289); called by muse, mutect2
- DST | c.5726G>T p.G1909V | Missense Mutation (SNP) | VAF 76/478 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); called by muse, varscan2
- DST | c.5725G>T p.G1909C | Missense Mutation (SNP) | VAF 78/482 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.911); called by muse, varscan2
- DTNA | c.1663-1G>T p.X555_splice | Splice Site (SNP) | VAF 17/136 reads (13%) | called by muse, mutect2, varscan2
- EFNA5 | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 15/110 reads (14%) | called by muse, varscan2
- EGFR | c.280A>T p.N94Y | Missense Mutation (SNP) | VAF 92/541 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF2AK4 | c.17G>C p.G6A | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELF1 | c.542A>T p.K181I | Missense Mutation (SNP) | VAF 53/455 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- ELF1 | c.541A>C p.K181Q | Missense Mutation (SNP) | VAF 53/454 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- ELF3 | c.292G>A p.D98N | Missense Mutation (SNP) | VAF 17/253 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2
- ELMO2 | c.79-7C>T | Splice Region (SNP) | VAF 46/401 reads (11%) | called by mutect2, varscan2
- ENO1 | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.833); called by muse, mutect2
- ENPP1 | c.510C>A p.C170* | Nonsense Mutation (SNP) | VAF 121/759 reads (16%) | called by muse, mutect2, varscan2
- EPB41L3 | c.3095A>T p.E1032V | Missense Mutation (SNP) | VAF 50/520 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EPC2 | c.1205G>C p.R402T | Missense Mutation (SNP) | VAF 39/566 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- EPHB3 | c.360del p.N121Tfs*35 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- ETHE1 | c.260G>C p.G87A | Missense Mutation (SNP) | VAF 27/159 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- EXOC6B | c.327+1G>T p.X109_splice | Splice Site (SNP) | VAF 60/680 reads (9%) | called by muse, mutect2
- F13A1 | c.2107C>A p.H703N | Missense Mutation (SNP) | VAF 55/327 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM120C | c.2863G>A p.G955R | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM155B | c.493_494del p.P165Sfs*5 | Frame Shift Del (DEL) | VAF 6/45 reads (13%) | called by mutect2, pindel, varscan2
- FAM183A | c.178G>T p.E60* | Nonsense Mutation (SNP) | VAF 46/402 reads (11%) | called by muse, mutect2, varscan2
- FAM227A | c.1619C>T p.S540L | Missense Mutation (SNP) | VAF 33/298 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM98C | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.018); called by muse, varscan2
- FAT1 | c.8036G>T p.G2679V | Missense Mutation (SNP) | VAF 27/337 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAT3 | c.7195T>A p.Y2399N | Missense Mutation (SNP) | VAF 32/324 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FBL | c.327G>T p.K109N | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- FBXO43 | c.1256A>T p.E419V | Missense Mutation (SNP) | VAF 34/544 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.296); called by muse, mutect2
- FCHO2 | c.215T>C p.V72A | Missense Mutation (SNP) | VAF 25/429 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.12); called by muse, mutect2
- FCRL5 | c.2086G>T p.E696* | Nonsense Mutation (SNP) | VAF 18/288 reads (6%) | called by muse, mutect2
- FGD3 | c.1132C>T p.Q378* | Nonsense Mutation (SNP) | VAF 13/108 reads (12%) | called by muse, mutect2, varscan2
- FGD4 | c.1213G>C p.E405Q | Missense Mutation (SNP) | VAF 65/559 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- FGD5 | c.1801C>T p.L601F | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- FGF6 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 47/287 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLG | c.3470C>A p.A1157E | Missense Mutation (SNP) | VAF 28/458 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- FLNB | c.443G>T p.W148L | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FLT3 | c.2435T>A p.L812Q | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLT3 | c.1883C>A p.T628K | Missense Mutation (SNP) | VAF 53/404 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- FN1 | c.3797C>T p.A1266V | Missense Mutation (SNP) | VAF 30/558 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.688); called by muse, mutect2
- FOCAD | c.1667G>T p.R556L | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- FOXD1 | c.380C>A p.P127H | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FOXP2 | c.1840-1G>T p.X614_splice | Splice Site (SNP) | VAF 74/804 reads (9%) | called by muse, mutect2
- FRMPD1 | c.138C>A p.N46K | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT tolerated (0.85); PolyPhen benign (0.023); called by muse, varscan2
- FSIP2 | c.8665G>T p.E2889* | Nonsense Mutation (SNP) | VAF 35/703 reads (5%) | called by muse, mutect2
- FSIP2 | c.14316A>G p.I4772M | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); called by muse, mutect2
- FTMT | c.488C>A p.A163D | Missense Mutation (SNP) | VAF 44/547 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- GABRB3 | c.1221G>T p.M407I | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- GADD45G | c.23G>A p.G8D | Missense Mutation (SNP) | VAF 13/325 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.054); called by muse, mutect2
- GBA | c.1037G>A p.G346D | Missense Mutation (SNP) | VAF 73/724 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GC | c.968T>A p.L323H | Missense Mutation (SNP) | VAF 54/962 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- GCNT3 | c.279G>T p.K93N | Missense Mutation (SNP) | VAF 46/286 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLYAT | c.811G>C p.A271P | Missense Mutation (SNP) | VAF 24/216 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GML | c.344C>A p.P115H | Missense Mutation (SNP) | VAF 103/749 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- GMNC | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 42/816 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by muse, mutect2
- GPHB5 | c.109G>C p.A37P | Missense Mutation (SNP) | VAF 14/191 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2
- GPI | c.914A>T p.Q305L | Missense Mutation (SNP) | VAF 47/294 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- GPR87 | c.640T>G p.L214V | Missense Mutation (SNP) | VAF 25/528 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- GPRC6A | c.2466C>A p.N822K | Missense Mutation (SNP) | VAF 50/340 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- GREM2 | c.476C>A p.S159Y | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- GRIN2D | c.1487C>T p.A496V | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- GRK7 | c.893C>G p.A298G | Missense Mutation (SNP) | VAF 41/292 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRM5 | c.94C>A p.P32T | Missense Mutation (SNP) | VAF 59/539 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- H2AZ1 | c.326-2A>G p.X109_splice | Splice Site (SNP) | VAF 21/282 reads (7%) | called by muse, mutect2
- H4C3 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 33/468 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- HDAC4 | c.1517A>G p.K506R | Missense Mutation (SNP) | VAF 13/288 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- HEATR5A | c.2580A>C p.L860F | Missense Mutation (SNP) | VAF 16/268 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- HEG1 | c.3347A>G p.H1116R | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2
- HELZ | c.549G>C p.L183F | Missense Mutation (SNP) | VAF 46/444 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HERC5 | c.2491G>C p.V831L | Missense Mutation (SNP) | VAF 15/312 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.16); called by muse, mutect2
- HHLA1 | c.1424A>T p.Q475L | Missense Mutation (SNP) | VAF 46/270 reads (17%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- HNRNPR | c.1343G>T p.G448V | Missense Mutation (SNP) | VAF 19/308 reads (6%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); called by muse, mutect2
- HOXB2 | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 22/171 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- HTATSF1 | c.2146A>G p.K716E | Missense Mutation (SNP) | VAF 24/422 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.113); called by muse, mutect2
- IFNA4 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 24/454 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.153); called by muse, mutect2
- IFNGR1 | c.430G>T p.D144Y | Missense Mutation (SNP) | VAF 153/969 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- IFT122 | c.1184C>T p.A395V (on ENST00000348417 / NM_052989.3; = p.A336V on NM_018262.4) | Missense Mutation (SNP) | VAF 30/654 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2
- IFT122 | c.1851+8G>T | Splice Region (SNP) | VAF 45/425 reads (11%) | called by muse, mutect2, varscan2
- IGHMBP2 | c.2839G>T p.E947* | Nonsense Mutation (SNP) | VAF 13/115 reads (11%) | called by muse, mutect2, varscan2
- IGLL5 | c.278A>T p.Q93L | Missense Mutation (SNP) | VAF 31/259 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGSF11 | c.719T>A p.I240N (on ENST00000393775 / NM_001015887.3; = p.I239N on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/310 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- IL1R1 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 83/755 reads (11%) | called by muse, mutect2
- IL1RAPL1 | c.1040T>A p.V347D | Missense Mutation (SNP) | VAF 57/431 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- IL36RN | c.181G>T p.V61F | Missense Mutation (SNP) | VAF 26/221 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ING3 | c.782A>T p.Q261L | Missense Mutation (SNP) | VAF 66/520 reads (13%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- INO80D | c.1448G>T p.C483F | Missense Mutation (SNP) | VAF 22/429 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- INSIG1 | c.556A>T p.N186Y | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- INSRR | c.256T>A p.F86I | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- INTS3 | c.3002C>T p.A1001V | Missense Mutation (SNP) | VAF 19/380 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- IQGAP2 | c.4393G>A p.D1465N | Missense Mutation (SNP) | VAF 15/269 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.021); called by muse, mutect2
- IQSEC2 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- ITPRID2 | c.3677T>G p.I1226S | Missense Mutation (SNP) | VAF 23/410 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); called by muse, mutect2
- JCAD | c.3878G>T p.R1293M | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- JPH2 | c.1165T>A p.S389T | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.241); called by muse, varscan2
- JUNB | c.611C>A p.T204N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, varscan2
- KAZN | c.1502T>A p.L501Q | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KCNH7 | c.1010T>A p.L337Q | Missense Mutation (SNP) | VAF 81/725 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- KCNJ3 | c.1465C>A p.P489T | Missense Mutation (SNP) | VAF 17/177 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.994); called by muse, mutect2
- KDM5D | c.4097C>T p.P1366L | Missense Mutation (SNP) | VAF 40/239 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- KEL | c.1306C>G p.R436G | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.148); called by muse, mutect2
- KIAA1755 | c.3344G>T p.G1115V | Missense Mutation (SNP) | VAF 23/160 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KIF26B | c.1460T>C p.L487P | Missense Mutation (SNP) | VAF 42/830 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.038); called by muse, mutect2
- KIF2B | c.1061G>T p.G354V | Missense Mutation (SNP) | VAF 40/344 reads (12%) | SIFT tolerated (0.66); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- KIR3DL3 | c.495G>C p.L165F | Missense Mutation (SNP) | VAF 30/291 reads (10%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.922); called by muse, mutect2
- KLHL3 | c.1651T>A p.L551M | Missense Mutation (SNP) | VAF 40/402 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL34 | c.1309G>C p.G437R | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- KMT2D | c.15931G>T p.V5311L | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KRT36 | c.235G>A p.G79R | Missense Mutation (SNP) | VAF 30/231 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- KRT86 | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 56/477 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KRTAP13-3 | c.268A>T p.N90Y | Missense Mutation (SNP) | VAF 43/373 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- KRTAP2-1 | c.383G>T p.C128F | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.16); called by muse, mutect2
- KRTAP22-1 | c.125C>A p.S42Y | Missense Mutation (SNP) | VAF 23/254 reads (9%) | PolyPhen benign (0); called by muse, mutect2
- KYNU | c.956-1G>C p.X319_splice | Splice Site (SNP) | VAF 26/612 reads (4%) | called by muse, mutect2
- L3MBTL1 | c.552G>T p.E184D (on ENST00000418998 / NM_001377303.1; = p.E94D on NM_015478.7) | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- LAMA1 | c.5050G>A p.D1684N | Missense Mutation (SNP) | VAF 79/545 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LAMA4 | c.2118T>G p.S706R (on ENST00000230538 / NM_001105206.3; = p.S699R on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 136/730 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LAMB4 | c.1409T>A p.V470E | Missense Mutation (SNP) | VAF 59/423 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- LAMB4 | c.120C>A p.N40K | Missense Mutation (SNP) | VAF 33/341 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- LATS2 | c.1772_1773del p.E591Vfs*12 | Frame Shift Del (DEL) | VAF 48/412 reads (12%) | called by pindel, varscan2
- LCE3D | c.106G>T p.G36C | Missense Mutation (SNP) | VAF 56/346 reads (16%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LGR5 | c.1717A>G p.T573A | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LHFPL3 | c.23C>A p.A8D | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); called by muse, mutect2
- LLGL1 | c.382G>C p.D128H | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.417); called by muse, varscan2
- LMX1B | c.533C>A p.S178Y | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.851); called by muse, mutect2
- LPA | c.4052G>A p.C1351Y | Missense Mutation (SNP) | VAF 84/613 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRAT | c.22G>T p.V8L | Missense Mutation (SNP) | VAF 21/268 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- LRCH1 | c.2155A>G p.I719V | Missense Mutation (SNP) | VAF 81/452 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRCH4 | c.883G>T p.D295Y | Missense Mutation (SNP) | VAF 26/254 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.176); called by muse, mutect2, varscan2
- LRP1B | c.12031G>A p.G4011R | Missense Mutation (SNP) | VAF 63/1088 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2
- LRRC14B | c.718del p.R240Gfs*52 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- LRRC37B | c.2348C>T p.S783L | Missense Mutation (SNP) | VAF 60/680 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.39); called by muse, mutect2
- LRTOMT | c.122T>A p.L41Q | Missense Mutation (SNP) | VAF 62/712 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.431); called by muse, mutect2
- LY75 | c.2454del p.I818Mfs*14 | Frame Shift Del (DEL) | VAF 48/512 reads (9%) | called by pindel, varscan2
- MAGEL2 | c.1855G>T p.A619S | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- MCCC1 | c.680A>T p.Q227L | Missense Mutation (SNP) | VAF 66/605 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- MED12L | c.4643T>A p.L1548H | Missense Mutation (SNP) | VAF 54/485 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MEGF8 | c.452A>T p.Q151L | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- MEGF8 | c.1571G>A p.S524N | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MEIOB | c.658C>A p.Q220K | Missense Mutation (SNP) | VAF 28/323 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.163); called by muse, mutect2
- MGAT3 | c.792C>G p.Y264* | Nonsense Mutation (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- MGAT4B | c.548T>C p.L183P | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- MMRN1 | c.2338C>A p.H780N | Missense Mutation (SNP) | VAF 20/346 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- MMRN1 | c.2340C>A p.H780Q | Missense Mutation (SNP) | VAF 20/345 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MNDA | c.1120C>A p.L374M | Missense Mutation (SNP) | VAF 37/423 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MPP3 | c.1085G>T p.G362V | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2
- MRC2 | c.3805G>T p.A1269S | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MRGPRD | c.332T>C p.V111A | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- MRGPRX4 | c.516G>T p.W172C | Missense Mutation (SNP) | VAF 41/309 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- MROH2B | c.1275G>T p.E425D | Missense Mutation (SNP) | VAF 30/250 reads (12%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MUC16 | c.31013C>A p.T10338N | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- MUC3A | c.9046G>T p.D3016Y | Missense Mutation (SNP) | VAF 40/519 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.973); called by muse, mutect2
- MVB12B | c.411G>C p.Q137H | Missense Mutation (SNP) | VAF 20/211 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- MYH14 | c.52G>T p.G18C | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- MYLK3 | c.1420A>T p.R474W | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); called by muse, mutect2
- MYO10 | c.3897-2A>T p.X1299_splice | Splice Site (SNP) | VAF 19/214 reads (9%) | called by muse, mutect2
- MYO3A | c.2794-2A>T p.X932_splice | Splice Site (SNP) | VAF 50/642 reads (8%) | called by muse, mutect2
- MYO6 | c.916A>T p.M306L | Missense Mutation (SNP) | VAF 144/855 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYT1L | c.3025G>T p.G1009* | Nonsense Mutation (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- NAB2 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NALCN | c.1696G>T p.A566S | Missense Mutation (SNP) | VAF 50/286 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- NAV1 | c.263A>T p.Q88L | Missense Mutation (SNP) | VAF 49/242 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NAV3 | c.5341G>A p.V1781M | Missense Mutation (SNP) | VAF 41/526 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.131); called by muse, mutect2
- NECTIN1 | c.280C>A p.R94S | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- NES | c.64T>C p.Y22H | Missense Mutation (SNP) | VAF 75/349 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NF1 | c.2101G>T p.E701* | Nonsense Mutation (SNP) | VAF 68/850 reads (8%) | called by muse, mutect2
- NFKBIZ | c.196G>C p.D66H | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- NLK | c.988A>G p.I330V | Missense Mutation (SNP) | VAF 34/755 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- NOTCH2 | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.914); called by muse, mutect2
- NOX3 | c.859T>A p.W287R | Missense Mutation (SNP) | VAF 63/354 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- NPHP4 | c.186C>G p.F62L | Missense Mutation (SNP) | VAF 13/208 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- NPHS1 | c.3133C>G p.P1045A | Missense Mutation (SNP) | VAF 15/277 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- NPY5R | c.494C>A p.T165K | Missense Mutation (SNP) | VAF 15/261 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.532); called by muse, mutect2
- NR5A1 | c.556C>G p.P186A | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- NRAP | c.1429-1G>T p.X477_splice (on ENST00000359988 / NM_001322945.2; = p.X442_splice on NM_006175.4) | Splice Site (SNP) | VAF 44/338 reads (13%) | called by muse, mutect2, varscan2
- NUP62 | c.1244A>T p.K415M | Missense Mutation (SNP) | VAF 48/401 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR1Q1 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 24/349 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); called by muse, mutect2
- OR2L13 | c.385C>A p.L129I | Missense Mutation (SNP) | VAF 126/640 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR2T10 | c.491T>A p.M164K | Missense Mutation (SNP) | VAF 26/372 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- OR52J3 | c.454A>G p.I152V | Missense Mutation (SNP) | VAF 14/452 reads (3%) | SIFT tolerated (0.66); PolyPhen benign (0.006); called by muse, mutect2
- OR5AN1 | c.432G>T p.W144C | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.518); called by muse, mutect2
- OR5B12 | c.716G>T p.C239F | Missense Mutation (SNP) | VAF 49/352 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- OR5H2 | c.563C>A p.P188Q | Missense Mutation (SNP) | VAF 36/350 reads (10%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OR6Q1 | c.379T>C p.Y127H | Missense Mutation (SNP) | VAF 26/252 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- OR6X1 | c.579G>T p.L193F | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); called by muse, mutect2
- ORC5 | c.1263-2A>T p.X421_splice | Splice Site (SNP) | VAF 34/264 reads (13%) | called by muse, mutect2, varscan2
- OTOG | c.1193C>A p.A398E | Missense Mutation (SNP) | VAF 21/162 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- OTX2 | c.593del p.G198Afs*8 (on ENST00000408990 / NM_172337.3; = p.G206Afs*8 on NM_021728.4) | Frame Shift Del (DEL) | VAF 71/708 reads (10%) | called by mutect2, pindel, varscan2
- OVCH1 | c.3027G>T p.W1009C | Missense Mutation (SNP) | VAF 33/235 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OVGP1 | c.1436T>C p.M479T | Missense Mutation (SNP) | VAF 19/360 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2
- OXCT1 | c.797T>C p.V266A | Missense Mutation (SNP) | VAF 101/818 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- PABPC4L | c.650T>G p.L217R | Missense Mutation (SNP) | VAF 30/547 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.751); called by muse, mutect2
- PACS2 | c.1666G>T p.A556S | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.884); called by muse, mutect2
- PADI1 | c.245C>G p.T82R | Missense Mutation (SNP) | VAF 17/163 reads (10%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- PAK5 | c.1743G>T p.R581= | Splice Region (SNP) | VAF 21/150 reads (14%) | called by muse, mutect2, varscan2
- PAK5 | c.276C>G p.I92M | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- PALB2 | c.2221G>T p.G741C | Missense Mutation (SNP) | VAF 89/783 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- PANK1 | c.841A>T p.T281S (on ENST00000307534 / NM_148977.2; = p.T56S on NM_138316.4) | Missense Mutation (SNP) | VAF 38/602 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.143); called by muse, mutect2
- PARD3B | c.3423G>C p.Q1141H (on ENST00000406610 / NM_001302769.2; = p.Q1072H on NM_057177.7) | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2
- PASD1 | c.1781C>A p.S594Y | Missense Mutation (SNP) | VAF 84/361 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- PCDH15 | c.2503G>T p.G835W | Missense Mutation (SNP) | VAF 56/658 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDH15 | c.571A>T p.I191F | Missense Mutation (SNP) | VAF 41/610 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PCDHA10 | c.1376A>G p.Y459C | Missense Mutation (SNP) | VAF 13/433 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHAC2 | c.1331G>T p.G444V | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.762); called by muse, varscan2
- PCDHAC2 | c.1411G>T p.E471* | Nonsense Mutation (SNP) | VAF 70/363 reads (19%) | called by muse, varscan2
- PCDHB12 | c.108G>T p.M36I | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, varscan2
- PCDHGA3 | c.1578A>T p.R526S | Missense Mutation (SNP) | VAF 40/474 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.589); called by muse, mutect2
- PCDHGB1 | c.2358dup p.A787Cfs*3 | Frame Shift Ins (INS) | VAF 60/566 reads (11%) | called by mutect2, pindel, varscan2
- PCDHGB3 | c.2147G>T p.R716L | Missense Mutation (SNP) | VAF 41/387 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- PCDHGB4 | c.2262dup p.A755Cfs*9 | Frame Shift Ins (INS) | VAF 70/721 reads (10%) | called by mutect2, pindel, varscan2
- PCLO | c.7409G>T p.S2470I | Missense Mutation (SNP) | VAF 65/399 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCLO | c.5857G>C p.E1953Q | Missense Mutation (SNP) | VAF 30/364 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2
- PCLO | c.2266C>T p.Q756* | Nonsense Mutation (SNP) | VAF 16/530 reads (3%) | called by muse, mutect2
- PCNT | c.153G>T p.Q51H | Missense Mutation (SNP) | VAF 50/530 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); called by muse, mutect2
- PCNX1 | c.2023A>G p.T675A | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2
- PCNX1 | c.6885+1G>T p.X2295_splice | Splice Site (SNP) | VAF 18/175 reads (10%) | called by muse, mutect2
- PDC | c.271C>A p.R91S | Missense Mutation (SNP) | VAF 36/408 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); called by muse, mutect2
- PDE1C | c.1207G>T p.D403Y | Missense Mutation (SNP) | VAF 53/398 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- PEX2 | c.229G>T p.G77* | Nonsense Mutation (SNP) | VAF 21/498 reads (4%) | called by muse, mutect2
- PFKFB4 | c.718T>C p.Y240H | Missense Mutation (SNP) | VAF 8/154 reads (5%) | PolyPhen probably damaging (0.998); called by muse, mutect2
- PGBD1 | c.577C>A p.H193N | Missense Mutation (SNP) | VAF 53/408 reads (13%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PGBD5 | c.826A>T p.S276C (on ENST00000525115; = p.S345C on NM_001258311.2) | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, varscan2
- PGLYRP4 | c.972G>C p.E324D | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- PHF19 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 47/524 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.018); called by muse, mutect2
- PHKG2 | c.16G>C p.G6R | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.386); called by muse, varscan2
- PHTF2 | c.160G>A p.D54N (on ENST00000248550 / NM_001366089.1; = p.D20N on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/217 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- PIK3C2A | c.467C>G p.S156C | Missense Mutation (SNP) | VAF 32/342 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.219); called by muse, mutect2
- PILRB | c.466A>T p.T156S | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- PKD1L1 | c.8063G>T p.G2688V | Missense Mutation (SNP) | VAF 68/578 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- PKP2 | c.1666T>A p.Y556N | Missense Mutation (SNP) | VAF 51/383 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- PLCE1 | c.4463A>G p.H1488R | Missense Mutation (SNP) | VAF 56/1004 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLEKHA6 | c.2156A>T p.K719M | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PLEKHO2 | c.759G>T p.E253D | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLK4 | c.743G>C p.R248T | Missense Mutation (SNP) | VAF 32/656 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.348); called by muse, mutect2
- PLOD2 | c.1767G>A p.W589* | Nonsense Mutation (SNP) | VAF 85/1073 reads (8%) | called by muse, mutect2
- PLRG1 | c.1508G>T p.S503I | Missense Mutation (SNP) | VAF 20/408 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2
- PLXNA1 | c.406G>T p.G136C | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PMPCB | c.329G>A p.G110D | Missense Mutation (SNP) | VAF 19/173 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPFIA2 | c.443A>T p.H148L | Missense Mutation (SNP) | VAF 38/339 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- PPFIA2 | c.442C>A p.H148N | Missense Mutation (SNP) | VAF 38/348 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- PPM1E | c.2170C>T p.Q724* | Nonsense Mutation (SNP) | VAF 31/449 reads (7%) | called by muse, mutect2
- PPP1R12C | c.2093G>A p.R698H | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PPP1R12C | c.400G>T p.G134C | Missense Mutation (SNP) | VAF 14/149 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PPP1R17 | c.151C>G p.Q51E | Missense Mutation (SNP) | VAF 36/440 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2
- PRKG1 | c.1471C>A p.H491N | Missense Mutation (SNP) | VAF 38/760 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PRPF6 | c.1187-1G>T p.X396_splice | Splice Site (SNP) | VAF 95/533 reads (18%) | called by muse, mutect2, varscan2
- PRRC2C | c.5594T>A p.I1865N (on ENST00000367742; = p.I1863N on NM_015172.4) | Missense Mutation (SNP) | VAF 72/429 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.598); called by muse, mutect2
- PSG11 | c.550G>T p.G184C | Missense Mutation (SNP) | VAF 77/718 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSKH2 | c.953C>A p.P318H | Missense Mutation (SNP) | VAF 33/312 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PSMD4 | c.244G>T p.G82C | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PSPC1 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPDC1 | c.1504G>T p.E502* (on ENST00000375360 / NM_177995.3; = p.E554* on NM_152422.4) | Nonsense Mutation (SNP) | VAF 24/340 reads (7%) | called by muse, mutect2
- RAB3GAP1 | c.2270A>T p.D757V | Missense Mutation (SNP) | VAF 57/552 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RAB3IP | c.780G>T p.L260F (on ENST00000550536 / NM_175623.4; = p.L244F on NM_022456.5) | Missense Mutation (SNP) | VAF 44/319 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RARA | c.913C>T p.L305F | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- RASGRF2 | c.110G>C p.S37T | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- RB1CC1 | c.3237A>T p.E1079D | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- RBBP6 | c.4201G>T p.G1401W | Missense Mutation (SNP) | VAF 12/293 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); called by muse, mutect2
- RBM39 | c.605T>A p.V202D | Missense Mutation (SNP) | VAF 18/478 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.021); called by muse, mutect2
- REV1 | c.1295G>T p.G432V | Missense Mutation (SNP) | VAF 55/622 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- RHAG | c.430A>G p.M144V | Missense Mutation (SNP) | VAF 64/902 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); called by muse, mutect2
- RIMS2 | c.2840G>T p.R947M (on ENST00000666250 / NM_001348490.2; = p.R755M on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/418 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- RIMS3 | c.653G>T p.C218F | Missense Mutation (SNP) | VAF 21/394 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); called by muse, mutect2
- RIMS3 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- RNF103 | c.382A>G p.R128G | Missense Mutation (SNP) | VAF 51/313 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RNF123 | c.1081G>T p.V361F | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- RNF19A | c.2164G>A p.D722N | Missense Mutation (SNP) | VAF 53/429 reads (12%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ROBO1 | c.1270G>T p.G424C | Missense Mutation (SNP) | VAF 47/521 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ROR2 | c.2087T>A p.L696Q | Missense Mutation (SNP) | VAF 21/310 reads (7%) | PolyPhen benign (0.005); called by muse, mutect2
- RPE65 | c.1487G>T p.G496V | Missense Mutation (SNP) | VAF 64/536 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- RPGRIP1 | c.1921G>T p.A641S | Missense Mutation (SNP) | VAF 77/537 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RPL4 | c.206C>A p.T69N | Missense Mutation (SNP) | VAF 29/255 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RSF1 | c.3631C>T p.Q1211* | Nonsense Mutation (SNP) | VAF 21/328 reads (6%) | called by muse, mutect2
- RTF2 | c.878A>T p.E293V | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- RTL9 | c.3222G>T p.M1074I | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- RUNX2 | c.1123C>A p.Q375K (on ENST00000371438; = p.Q353K on NM_001015051.3) | Missense Mutation (SNP) | VAF 38/603 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.519); called by muse, mutect2
- RYR1 | c.7301G>C p.G2434A | Missense Mutation (SNP) | VAF 29/276 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RYR1 | c.9512G>T p.S3171I | Missense Mutation (SNP) | VAF 40/443 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SALL4 | c.2127del p.T710Rfs*13 | Frame Shift Del (DEL) | VAF 37/341 reads (11%) | called by mutect2, pindel, varscan2
- SBSN | c.263A>T p.Q88L | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SDK1 | c.2321A>T p.N774I | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, varscan2
- SELENOV | c.212C>A p.T71N | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.278); called by muse, mutect2, varscan2
- SELP | c.1256G>T p.G419V | Missense Mutation (SNP) | VAF 15/326 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEMA5B | c.2394C>A p.F798L | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- SEPTIN14 | c.393C>A p.Y131* | Nonsense Mutation (SNP) | VAF 15/82 reads (18%) | called by muse, mutect2, varscan2
- SEPTIN7 | c.630G>T p.Q210H | Missense Mutation (SNP) | VAF 37/346 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SHANK1 | c.1885A>G p.R629G | Missense Mutation (SNP) | VAF 46/363 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SHISA7 | c.663C>A p.N221K | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); called by muse, varscan2
- SHOX2 | c.481G>A p.E161K (on ENST00000441443 / NM_006884.3; = p.E185K on NM_003030.4) | Missense Mutation (SNP) | VAF 62/590 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SLC13A1 | c.1591G>T p.V531L | Missense Mutation (SNP) | VAF 47/591 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); called by muse, mutect2
- SLC22A12 | c.755C>A p.A252D | Missense Mutation (SNP) | VAF 17/236 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SLC5A12 | c.64T>C p.S22P | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.391); called by muse, mutect2
- SLC6A5 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC9A6 | c.1417dup p.Y473Lfs*39 | Frame Shift Ins (INS) | VAF 24/262 reads (9%) | called by mutect2, pindel
- SLC9A9 | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 65/641 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLITRK2 | c.914C>A p.P305H | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SNRPD3 | c.83A>T p.Y28F | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- SNU13 | c.210del p.L71Cfs*42 | Frame Shift Del (DEL) | VAF 23/272 reads (8%) | called by mutect2, pindel*
- SNUPN | c.592G>C p.D198H | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- SNX13 | c.2428G>T p.G810C | Missense Mutation (SNP) | VAF 34/327 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SNX30 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 39/317 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- SOCS5 | c.137G>A p.S46N | Missense Mutation (SNP) | VAF 46/600 reads (8%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); called by muse, mutect2
- SPCS3 | c.337G>C p.G113R | Missense Mutation (SNP) | VAF 16/387 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SPON1 | c.1702G>A p.D568N | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- SPTBN4 | c.4525del p.R1509Afs*136 | Frame Shift Del (DEL) | VAF 7/57 reads (12%) | called by mutect2, pindel
- ST18 | c.2853G>T p.Q951H | Missense Mutation (SNP) | VAF 16/293 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2
- ST3GAL3 | c.515G>A p.C172Y (on ENST00000361392 / NM_174964.4; = p.C157Y on NM_006279.5) | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- STARD3NL | c.463G>A p.V155M | Missense Mutation (SNP) | VAF 38/442 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2
- STMND1 | c.781G>A p.V261I | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.026); called by muse, mutect2
- SUPT20HL2 | c.1568C>A p.A523E | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SYNE1 | c.23940G>T p.W7980C (on ENST00000367255 / NM_182961.4; = p.W7909C on NM_033071.3) | Missense Mutation (SNP) | VAF 127/795 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNE1 | c.19219C>T p.L6407F (on ENST00000367255 / NM_182961.4; = p.L6336F on NM_033071.3) | Missense Mutation (SNP) | VAF 58/882 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); called by muse, mutect2
- SYNPO | c.994A>T p.S332C (on ENST00000394243 / NM_001166208.2; = p.S88C on NM_007286.6) | Missense Mutation (SNP) | VAF 67/247 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- SYNPO2 | c.1474G>T p.A492S | Missense Mutation (SNP) | VAF 16/293 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); called by muse, mutect2
- TAF4B | c.1331C>G p.T444R | Missense Mutation (SNP) | VAF 31/412 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.216); called by muse, mutect2
- TAT | c.605A>C p.E202A | Missense Mutation (SNP) | VAF 35/889 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.63); called by muse, mutect2
- TBATA | c.823C>A p.P275T | Missense Mutation (SNP) | VAF 33/293 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2
- TBC1D8 | c.1081C>A p.P361T | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); called by muse, mutect2
- TBL1XR1 | c.745G>T p.A249S | Missense Mutation (SNP) | VAF 51/724 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2
- TBX21 | c.1526del p.G509Vfs*32 | Frame Shift Del (DEL) | VAF 12/113 reads (11%) | called by mutect2, pindel, varscan2
- TENM4 | c.8182G>T p.V2728L | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TENM4 | c.1143G>T p.E381D | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.079); called by muse, mutect2
- TFAP4 | c.232A>T p.T78S | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TIMELESS | c.2714G>T p.R905L | Missense Mutation (SNP) | VAF 37/335 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- TINAG | c.686G>T p.G229V | Missense Mutation (SNP) | VAF 38/493 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); called by muse, mutect2
- TMEM132E | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM170B | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 71/442 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM200A | c.1390T>C p.S464P | Missense Mutation (SNP) | VAF 78/431 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMEM237 | c.622G>A p.V208M (on ENST00000409883 / NM_001044385.3; = p.V200M on NM_152388.4) | Missense Mutation (SNP) | VAF 50/676 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.006); called by muse, mutect2
- TNC | c.2469G>A p.W823* | Nonsense Mutation (SNP) | VAF 9/157 reads (6%) | called by muse, mutect2
- TNIK | c.523A>T p.S175C | Missense Mutation (SNP) | VAF 36/442 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TNRC18 | c.2096G>T p.R699L | Missense Mutation (SNP) | VAF 56/274 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- TOPAZ1 | c.2766-2A>T p.X922_splice | Splice Site (SNP) | VAF 36/272 reads (13%) | called by muse, mutect2, varscan2
- TOR2A | c.512T>C p.M171T | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.019); called by muse, mutect2
- TPR | c.5605G>A p.E1869K | Missense Mutation (SNP) | VAF 19/469 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); called by muse, mutect2
- TPR | c.3565G>T p.E1189* | Nonsense Mutation (SNP) | VAF 70/426 reads (16%) | called by muse, mutect2, varscan2
- TRAPPC4 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- TRIM42 | c.2060C>A p.P687H | Missense Mutation (SNP) | VAF 45/355 reads (13%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM64C | c.843G>T p.M281I | Missense Mutation (SNP) | VAF 72/648 reads (11%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.521); called by muse, varscan2
- TRIO | c.5176G>T p.E1726* | Nonsense Mutation (SNP) | VAF 25/134 reads (19%) | called by muse, mutect2, varscan2
- TRPM2 | c.2890G>T p.D964Y | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TRPM8 | c.3124G>C p.V1042L | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- TSPAN5 | c.322G>T p.A108S | Missense Mutation (SNP) | VAF 34/494 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.297); called by muse, mutect2
- TTC28 | c.3509C>T p.S1170L | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); called by muse, mutect2
460 further variants in this file (59 protein-altering or splice-affecting, 244 silent, 157 other) are not listed here.
